Somatic mutation profile of tumor specimen fc0aa1e4-c1d8-43ed-a5cd-038f61 (aliquot fc0aa1e4-c1d8-43ed-a5cd-038f61_D6_1) from CPTAC case 11BR059, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.9 years (16,759 days).
Specimen fc0aa1e4-c1d8-43ed-a5cd-038f61: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f8809f-d4a0-461f-8828-76bb79e1e313.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b8534837-c177-4fcd-9778-dd7844 (Blood Derived Normal), aliquot b8534837-c177-4fcd-9778-dd7844_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0b81fb9-4e99-4a8e-8878-0c3282755ae0

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Splice Region 2, Nonsense Mutation 2, RNA 2, Frame Shift Ins 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 25/129 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AIPL1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1445697118; called by muse, mutect2
- ARMCX2 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57529808; called by muse, mutect2, varscan2
- ATP1A2 | c.633G>A p.V211= | Splice Region (SNP) | VAF 41/402 reads (10%) | catalogued as rs1054187251; called by muse, mutect2, varscan2
- B3GAT3 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs372593851; called by muse, mutect2
- C7orf25 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs1246471399; called by muse, mutect2
- CDC5L | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.114); catalogued as rs745967167, COSV65177621; called by mutect2, varscan2
- EFHC1 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 18/397 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100932051; called by muse, mutect2
- GPX2 | c.221A>C p.Q74P | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50824732; called by muse, mutect2
- H2BU1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV100797249; called by muse, mutect2
- MBD3 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV50084659; called by muse, varscan2
- NAA35 | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs906608648; called by mutect2, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 14/105 reads (13%) | catalogued as rs1413029182; called by mutect2, varscan2
- SHANK2 | c.3784C>T p.P1262S | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.066); catalogued as COSV53592097; called by muse, mutect2
- SLCO1C1 | c.1783G>C p.A595P | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV56878794; called by muse, mutect2
- STK36 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs1243212570, COSV55329183; called by muse, mutect2, varscan2
- STK38L | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1326997121; called by muse, mutect2, varscan2
- TIMELESS | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770377436, COSV99973709; called by muse, mutect2
- TRIP12 | c.5515G>C p.D1839H | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV52261451; called by muse, mutect2
- TRMO | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as rs1466496367; called by muse, mutect2
- AFF4 | c.1991A>T p.Q664L | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC134 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDK12 | c.2770T>G p.C924G | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRNA4 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- DDX18 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DENND4A | c.2400G>A p.M800I | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- EN1 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2
- ERAP1 | c.1943G>A p.S648N | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- EVI2A | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EXPH5 | c.2908G>C p.E970Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- LONP2 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LYSMD4 | c.548C>T p.S183L (on ENST00000409796 / NM_001284417.2; = p.S184L on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- MAGED2 | c.1598C>G p.A533G | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2
- MAN2B1 | c.1129T>G p.F377V | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- MSR1 | c.9G>C p.L3F | Missense Mutation (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- PCDH9 | c.1914G>C p.Q638H | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHKA1 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2
- RIMS2 | c.3565G>T p.E1189* | Nonsense Mutation (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- SEPTIN7 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SMYD1 | c.214C>A p.H72N | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); called by muse, mutect2
- SRGAP1 | c.2910G>C p.L970F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSRP1 | c.1040C>G p.A347G | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- SST | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); called by mutect2, varscan2
- TAZ | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 32/391 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- TCF20 | c.2879C>G p.S960C | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- WBP1L | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XAB2 | c.51C>T p.F17= | Splice Region (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- ZEB1 | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF781 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2
- ABCE1 | c.261T>C p.Y87= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2, varscan2
- APOLD1 | c.402C>T p.I134= (on ENST00000326765 / NM_001130415.2; = p.I103= on NM_030817.3) | Silent (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- CALHM1 | c.942G>T p.R314= | Silent (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- CDH7 | c.1482C>A p.A494= | Silent (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- CHRNA7 | c.630T>C p.Y210= | Silent (SNP) | VAF 28/205 reads (14%) | catalogued as COSV100181408; called by muse, mutect2, varscan2
- CLDN6 | c.165G>A p.V55= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as rs569805298; called by muse, mutect2, varscan2
- GAS2L1 | c.471C>T p.L157= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs919640330; called by muse, mutect2, varscan2
- H2AC20 | c.252C>T p.L84= | Silent (SNP) | VAF 14/295 reads (5%) | catalogued as COSV58611547; called by muse, mutect2
- HCFC1 | c.2532C>T p.T844= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs782372754; called by mutect2, varscan2
- LARP6 | c.279C>A p.I93= | Silent (SNP) | VAF 20/388 reads (5%) | called by muse, mutect2
- NEB | c.19347C>T p.F6449= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- P2RY12 | c.723C>A p.I241= | Silent (SNP) | VAF 28/242 reads (12%) | called by muse, mutect2, varscan2
- PLOD2 | c.417A>G p.A139= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- RCC2 | c.390C>G p.R130= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- RUSC2 | c.3426G>A p.L1142= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- TPO | c.444G>T p.A148= | Silent (SNP) | VAF 16/382 reads (4%) | called by muse, mutect2
- ZNF84 | c.438A>C p.P146= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- AC009533.1 | n.1111G>A | RNA (SNP) | VAF 23/425 reads (5%) | catalogued as rs1480180862; called by muse, mutect2
- EP400P1 | n.1071C>T | RNA (SNP) | VAF 21/200 reads (11%) | catalogued as rs1410098161; called by muse, varscan2
- GANC | c.201+2504G>A | Intron (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*558C>T | 3'UTR (SNP) | VAF 38/257 reads (15%) | catalogued as rs1329565433; called by muse, mutect2, varscan2
